Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7479, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7479-01A (Primary Tumor).

ADDENDUM DISCUSSION:

Most of the neoplastic cells are reactive for GFAP, however, some of the larger cells with halos are GFAP negative. Neu-N demonstrates that the tumor cells are negative for Neu-N with only cortical neurons being positive. The atypical cells, including the large cells without obvious processes are strongly reactive for p53, suggesting astrocytic lineage. There is variable immunoreactivity for MIB-1. Slide 1A has a labeling index of <0.5% while 2A demonstrates a labeling index of up to 9.2%.

ADDENDUM DIAGNOSIS:

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:
ANAPLASTIC ASTROCYTOMA (WHO GRADE III).
MIB-1 LABELING INDEX = <0.5% UP TO 9.2%.

COMMENT: Despite the absence of significant mitoses, the degree of atypia, along with the high MIB-1 labeling index warrants the diagnosis of grade III/anaplastic.

ADDENDUM MICROSCOPIC DESCRIPTION:

2. Sections demonstrate a neoplastic proliferation of glial cells that diffusely infiltrate the gray and white matter. Hypercellular is quite modest. However, atypia ranges from mild to marked. There is variably prominent autolytic change that results in artifactual perinuclear halos surrounding neurons in the gray matter. However, in addition, many of the atypical cells as well as smaller cells have halos that appear to be real and likely represent oligodendroglioma differentiation. In other areas, the tumor appears astrocytic. No mitotic figures are seen despite the atypia. There is no microvascular proliferation or necrosis.

Source: NCI Genomic Data Commons file 1d821f8c-824c-4387-8416-756f18d1f2ce (TCGA-HT-7479.9BDF94B6-7E28-4C01-A392-C1FF7FD150D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).